TCGA case TCGA-2G-AAG2 — Testicular Germ Cell Tumors (TCGA-TGCT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Germ Cell Neoplasms; Primary site: Testis. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/66c81ec3-7a4a-4eb3-bf32-531a74350d85

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Netherlands; Age at index: 24 years; Year of birth: 1985; Vital status: Alive.

Diagnoses (1)
1. Choriocarcinoma, NOS: ICD-O-3 morphology code: 9100/3; ICD-10 code: C62.9; Tissue or organ of origin: Testis, NOS; Site of resection or biopsy: Testis, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 24.5 years (8,957 days); Year of diagnosis: 2010; Method of diagnosis: Orchiectomy; AJCC staging edition: 7th; AJCC clinical T: T1; AJCC clinical N: N2; AJCC clinical M: M0; AJCC clinical stage: Stage IIB; AJCC pathologic T: T1; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; IGCCCG stage: Good Prognosis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,766 days (4.8 years); Ajcc serum tumor markers: S1.
   Pathology details: Intratubular germ cell neoplasia present: Yes; Lymphatic invasion present: No; Vascular invasion present: No.
   Pathology details: Lymph node dissection site: Retroperitoneal; Lymph nodes removed: Yes; Timepoint category: Post Adjuvant Therapy.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bleomycin + Cisplatin + Etoposide; Treatment intent type: Adjuvant; Days to treatment start: 11 days; Days to treatment end: 58 days; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Surgery, NOS; Treatment anatomic sites: Testis.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 1,430 days (3.9 years); Disease response: Tumor Free.
- Days to follow up: 1,766 days (4.8 years); Disease response: Tumor Free.
- Karnofsky performance status: 100; ECOG performance status: 0; Timepoint: Follow-up.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day -3: Lactate Dehydrogenase 219; Alpha Fetoprotein 1.2; Human Chorionic Gonadotropin 3266.
- Day 11: Lactate Dehydrogenase 275; Alpha Fetoprotein 1; Human Chorionic Gonadotropin 1932.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Fertility history: Conceived 1 or more children by natural conception; Undescended testis history: No.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-2G-AAG2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 90 mg.
  Slide TCGA-2G-AAG2-01A-01-TS1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 40; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-2G-AAG2-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-2G-AAG2-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
